Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JU, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JU-01A (Primary Tumor).

[page 1 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: F
ADM DATE:

PAT TYPE:

OPER DATE:

PROCEDURE: APMI

ADDENDUM REPORT FOLLOWING IMMUNOHISTOCHEMISTRY:

To further evaluate this adrenocortical carcinoma, immunohistochemical stains for p53, beta-catenin and Ki-67 were performed.

Please see diagnosis and COMMENT below.

PROCEDURE: APDX

1. Right adrenal gland, resection: Adrenocortical carcinoma, low-grade by mitotic activity. Margins negative. Please see previous report and COMMENT below.

COMMENT:

This low-grade adrenocortical carcinoma shows a variety of histologic patterns. A p53 immunostain shows a focal area with nuclear pleomorphism to be positive for nuclear immunoreactivity within this region, raising the possibility of an early and focal p53 mutation. The Ki-67 immunostain shows an increased MIB-1 labeling index within this p53-positive region. Throughout the neoplasm, the beta-catenin stain shows a membranous immunoreactive pattern, consistent with the absence of a WNT pathway activation. The p53 and MIB-1 results together raise the possibility that this low-grade adrenocortical carcinoma has developed a focal high-grade component. However, the clinical significance of a focal high-grade component is unknown.

The signing staff pathologist, have personally examined and interpreted the slides from this case.

"This test was developed and its performance characteristics determined by the
It has not been
cleared or approved by the U.S. Food and Drug Administration. (The FDA has
determined that such clearance is not necessary. This test is used for
clinical purposes. It should not be regarded as investigational or for
research. This laboratory is certified under the Clinical Laboratory
Improvement Amendments of 1988 ["CLIA"] as qualified to perform high
complexity testing)."

ICD-O-3

Carcinoma, adrenal cortical 8370/3

Site: Adrenal Gland, cortex C74.0

QID 11/30/13

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: _____

PAGE #: 2

BIRTHDATE: _____

SEX: F

ADM DATE: _____

OPER DATE: _____

OPER DATE: _____

PROCEDURE: SPHS

Right adrenal mass and hepatic cyst and cortisol production. Concern for adrenal cortical carcinoma. Operative Procedure: Right adrenalectomy, possible hepatic cyst removal.

PROCEDURE: SPGD

1. "Right adrenal gland, 2 short stitch = superior, 1 long = lateral, 2 long = posterior, concern for ACC" Received in formalin is a 160 gram, 8.7 cm superior to inferior x 7.7 cm medial to lateral x 4.9 cm anterior to posterior adrenalectomy specimen that contains an 8.5 x 5.2 x 4.8 cm tumor and a small amount of attached adipose tissue. The tumor appears to arise from the adrenal cortex and has fleshy, tan cut surfaces with bright orange foci. A 4.5 x 4.2 x 3.9 cm area of the tumor is soft and yellow-white, probably necrotic. The tumor is well-circumscribed and closely approaches all margins but there is freely mobile capsule at all margins. Single short stitch superior. Single long stitch is lateral. Double long stitch is posterior. Anterior inked yellow, posterior inked black, superior blue, inferior green, medial red, lateral orange. Gross photographs taken.

1A. Tumor to superior margin.

1B. Tumor to inferior margin.

1C. Tumor to anterior margin.

1D. Tumor to posterior margin.

1E. Tumor to lateral margin.

1F-H. Tumor to medial margin with adrenal gland.

1I-J. Additional representative sections of tumor.

2. "Right liver cyst wall" Received in formalin is a 7.4 x 2.7 x 0.4 cm portion of tissue with a pink-tan, smooth surface on one side and a pink-red ragged surface on the other side. No masses or lesions are identified. Two representative sections submitted in cassette 2A.

PROCEDURE: SPMI

ADRENOCORTICAL CARCINOMA

V4

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

BIRTHDATE:

PAGE #: 3

SEX: F

ADM DATE:

PAT TYPE:

OPER DATE:

Tumor Size: 8.5 x 5.2 x 4.8 cm

Tumor Weight: 160 grams

Capsular Invasion: Present.

Vascular Invasion: Absent

Surgical Margins: Negative

Necrosis: Present

Mitotic Rate: 10 per 50 high-power fields

Grade: Low

Lymph nodes status: N.A.

Extra-adrenal extension: Present.

Stage: T3NXMX

Immunohistochemistry Results: N/A

PROCEDURE: SPDX

1. Right adrenal gland, resection: Adrenal cortical carcinoma (8.5 cm), low-grade. Margins negative. Please see template above for details.

2. Right liver cyst wall, excision: Simple cyst.

The signing staff pathologist, have personally examined and interpreted the slides from this case.

Source: NCI Genomic Data Commons file 99b58ffd-3cb6-4738-9bd3-fc4cec8f00a3 (TCGA-OR-A5JU.2D791779-66E6-408C-B479-CC74246F0EA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).